TCGA case TCGA-2G-AAH4 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d1e7a280-963a-48b0-b6fb-1acf7c1a435e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 34 years; Year of birth: 1963; Vital status: Alive.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 34.2 years (12,481 days); Year of diagnosis: 1997; Method of diagnosis: Orchiectomy; AJCC staging edition: 4th; AJCC clinical T: T1; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; IGCCCG stage: Intermediate Prognosis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 6,210 days (17.0 years); Ajcc serum tumor markers: S2.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: Yes; Timepoint category: Post Adjuvant Therapy.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bleomycin + Cisplatin + Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 9 days; Days to treatment end: 95 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 3,823 days (10.5 years); Disease response: Tumor Free.
- Days to follow up: 6,210 days (17.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -10: Lactate Dehydrogenase 264; Alpha Fetoprotein 1191; Human Chorionic Gonadotropin 214.
- Day 1: Lactate Dehydrogenase 230; Alpha Fetoprotein 727; Human Chorionic Gonadotropin 70.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAH4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 310 mg.
  Slide TCGA-2G-AAH4-01A-01-TS1: Section location: Top; Percent tumor cells: 93; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 7; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAH4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAH4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; History fertility: Fathered > or = 1 child by natural conception; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Postoperative treatment list: Postoperative treatment: Pharmaceutical.
- Stage record: Igcccg stage: Intermediate.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Present; Lymphovascular invasion: No; Post orchi lymph node dissection: Yes - After chemotherapy; First treatment success: Normalization of Tumor Markers, but Residual Tumor Mass.
- Primary pathology, Histology list, Histology 1: Histologic diagnosis: Non-Seminoma, Yolk Sac Tumor.
- Primary pathology, Histology list, Histology 2: Histologic diagnosis: Non-Seminoma, Embryonal Carcinoma; Histologic diagnosis percent: 10.
- Primary pathology, Histology list, Histology 3: Histologic diagnosis: Non-Seminoma, Teratoma (Mature); Histologic diagnosis percent: 5.
- Primary pathology, Histology list, Histology 4: Histologic diagnosis: Seminoma, NOS; Histologic diagnosis percent: 5.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 264; Pre orchi hcg: 214; Pre orchi afp: 1191.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 230; Post orchi hcg: 70; Post orchi afp: 727.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: Yes - After chemotherapy; Tumor status: Tumor free; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: Yes - After chemotherapy; Tumor status: Tumor free; Treatment outcome first course: Normalization of Tumor Markers, but Residual Tumor Mass; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 6,210 days; disease-specific survival: no event (censored), 6,210 days; progression-free interval: no event (censored), 6,210 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAH4-01A-12D-A42X-01): tumor purity 0.85, ploidy 2.8, whole-genome doublings 1.
